CCDI case PBCBAJ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/5653ccd9-ea74-4ae0-b4d2-16504381612b

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.3 years (5,219 days).

Biospecimens (3 samples)
- Sample 0DQ55A: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DQ55K: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DQ55R: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
